Somatic mutation profile of tumor specimen C3N-02764-02 (aliquot CPT0184350010) from CPTAC case C3N-02764, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 66.6 years (24,321 days).
Specimen C3N-02764-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 029a527c-b462-4710-980b-d263462c8eda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02764-71 (Blood Derived Normal), aliquot CPT0184400002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8391b0ce-c92b-4eda-adb5-b3191e54cdb8

The open-access MAF lists 903 somatic variants for this specimen: 585 protein-altering or splice-affecting, 208 silent, 110 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 489, Silent 208, Nonsense Mutation 51, Intron 46, 5'UTR 18, 3'UTR 15, Frame Shift Del 14, RNA 14, Splice Site 13, Splice Region 12, 5'Flank 10, 3'Flank 7.

Variants (750 of 903; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.919+1G>T p.X307_splice | Splice Site (SNP) | VAF 198/491 reads (40%) | hotspot (GDC flag); catalogued as rs1131691039, CD920913, CS107068, CS120864, COSV52683145, COSV52775982, COSV52814989; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 121/535 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144653790, COSV57061110; called by muse, mutect2, varscan2
- AC138647.1 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious, low confidence (0); catalogued as COSV70194576; called by muse, mutect2, varscan2
- ACSL6 | c.1012G>T p.G338* (on ENST00000379240; = p.G363* on NM_015256.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 58/124 reads (47%) | catalogued as COSV57295967; called by muse, mutect2, varscan2
- ACSM5 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1253807890, COSV59371128; called by muse, mutect2, varscan2
- ACSS3 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 149/266 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV54100264, COSV99699640; called by muse, mutect2, varscan2
- ADGRG6 | c.656A>G p.K219R | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs1187834530; called by muse, mutect2, varscan2
- AFF4 | c.1753G>C p.E585Q | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs1214814384; called by muse, mutect2, varscan2
- AMBRA1 | c.1621G>C p.E541Q (on ENST00000458649 / NM_001367468.1; = p.E451Q on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/302 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); catalogued as COSV100095562, COSV54052409; called by muse, mutect2, varscan2
- AMPD1 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 36/426 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.567); catalogued as rs561023947, COSV62415988; called by muse, mutect2
- ANKRD30A | c.2542-1G>T p.X848_splice (on ENST00000611781; = p.X792_splice on NM_052997.2) | Splice Site (SNP) | VAF 48/142 reads (34%) | catalogued as rs764278893, COSV64608261; called by muse, mutect2, varscan2
- APCDD1 | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 42/339 reads (12%) | catalogued as rs775104994; called by muse, mutect2, varscan2
- APOB | c.11575G>A p.E3859K | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1378283331; called by muse, mutect2, varscan2
- APOB | c.8855G>T p.G2952V | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.642); catalogued as rs369472561, COSV99265040; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARMC9 | c.879+3G>A | Splice Region (SNP) | VAF 24/222 reads (11%) | catalogued as rs776773208; called by muse, mutect2, varscan2
- ASIC2 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.309); catalogued as rs781592193; called by muse, mutect2, varscan2
- ATP10D | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 99/389 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as rs946132651; called by muse, mutect2, varscan2
- ATP1A4 | c.1291C>T p.R431* | Nonsense Mutation (SNP) | VAF 16/216 reads (7%) | catalogued as rs369199390; called by muse, mutect2
- AURKC | c.397C>A p.Q133K (on ENST00000302804 / NM_001015878.2; = p.Q99K on NM_003160.3) | Missense Mutation (SNP) | VAF 60/505 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV100248923; called by muse, mutect2, varscan2
- BAZ2B | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.944); catalogued as COSV58595664; called by muse, varscan2
- BEND4 | c.591G>T p.M197I | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as COSV72469114; called by muse, mutect2, varscan2
- BICC1 | c.1760C>T p.S587L | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV99570846; called by muse, mutect2, varscan2
- BOC | c.2553C>G p.S851R | Missense Mutation (SNP) | VAF 150/331 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56350715; called by muse, mutect2, varscan2
- BRAF | c.612G>C p.E204D | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.364); catalogued as rs1202874043, COSV56348198; called by muse, mutect2, varscan2
- C7 | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV57479052; called by mutect2, varscan2
- C8A | c.463G>C p.G155R | Missense Mutation (SNP) | VAF 179/514 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1018655444; called by muse, mutect2, varscan2
- CCDC151 | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 35/123 reads (28%) | catalogued as COSV62697931; called by muse, mutect2, varscan2
- CCDC71L | c.635G>A p.R212K | Missense Mutation (SNP) | VAF 59/317 reads (19%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.013); catalogued as rs764570917; called by muse, mutect2, varscan2
- CCDC96 | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.101); catalogued as rs764841283; called by muse, mutect2, varscan2
- CCPG1 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as rs1456566805; called by muse, mutect2, varscan2
- CDKL5 | c.2941C>G p.R981G | Missense Mutation (SNP) | VAF 90/170 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs374054249, COSV66106319; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CDKN2AIP | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV56627850; called by muse, mutect2, varscan2
- CENPQ | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100225695; called by muse, mutect2, varscan2
- CEP290 | c.6952G>C p.E2318Q | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs1219694248; called by muse, mutect2
- CFAP299 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as rs375423593, COSV100812571, COSV63881323; called by muse, mutect2, varscan2
- CLCN1 | c.2542C>A p.L848I | Missense Mutation (SNP) | VAF 61/315 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as rs1482476297; called by muse, mutect2, varscan2
- CMYA5 | c.8905G>C p.E2969Q | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1203359813; called by muse, mutect2, varscan2
- CNTNAP2 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 31/305 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.093); catalogued as rs749043222, COSV62271176; called by muse, mutect2, varscan2
- CNTNAP5 | c.2805G>C p.L935F | Missense Mutation (SNP) | VAF 25/290 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV70507425; called by muse, mutect2
- COG7 | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1413701149, COSV56153637; called by muse, varscan2
- COL26A1 | c.672G>T p.Q224H (on ENST00000313669 / NM_001278563.3; = p.Q222H on NM_133457.4) | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58128214; called by muse, mutect2, varscan2
- COL5A2 | c.1454del p.P485Qfs*10 | Frame Shift Del (DEL) | VAF 78/238 reads (33%) | catalogued as COSV66415225; called by mutect2, pindel, varscan2
- CPLANE2 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 33/280 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1051751058; called by muse, mutect2, varscan2
- CRAMP1 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as rs1404587625; called by muse, mutect2, varscan2
- CSPP1 | c.2551G>A p.E851K (on ENST00000676605; = p.E810K on NM_024790.6) | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.307); catalogued as COSV99139570; called by muse, mutect2, varscan2
- CWH43 | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs761346667; called by muse, mutect2
- DBF4 | c.1480G>C p.D494H | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV55997946; called by muse, mutect2, varscan2
- DENND2C | c.1838G>C p.R613T (on ENST00000393274 / NM_001256404.2; = p.R556T on NM_198459.4) | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422609598; called by muse, mutect2, varscan2
- DIO2 | c.430C>G p.R144G | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs553834317, COSV70445038, COSV70445783; called by muse, mutect2, varscan2
- DIP2B | c.1708G>T p.G570C | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV56592688; called by muse, mutect2, varscan2
- DMRT1 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs764833251; called by muse, mutect2, varscan2
- DNAH5 | c.11752C>T p.L3918F | Missense Mutation (SNP) | VAF 46/324 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV99443180; called by muse, mutect2, varscan2
- EBF1 | c.533C>G p.S178* | Nonsense Mutation (SNP) | VAF 44/165 reads (27%) | catalogued as COSV58178454; called by muse, mutect2, varscan2
- EDARADD | c.329C>G p.P110R (on ENST00000334232 / NM_145861.4; = p.P100R on NM_080738.4) | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV62064689; called by muse, mutect2
- EDEM2 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 24/303 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556734937; called by muse, mutect2
- EEF1AKMT2 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1191438423; called by muse, mutect2, varscan2
- EGFR | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 201/535 reads (38%) | catalogued as rs1175454134, COSV51817262; called by muse, mutect2, varscan2
- ERBB2 | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 97/305 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV54063501, COSV54069910; called by muse, mutect2, varscan2
- ERCC8 | c.730C>G p.H244D | Missense Mutation (SNP) | VAF 32/372 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM163462; called by muse, mutect2
- ESRRB | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 113/381 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.28); catalogued as COSV55058371; called by muse, mutect2, varscan2
- ESS2 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 34/109 reads (31%) | catalogued as COSV99350619; called by muse, mutect2, varscan2
- F2 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 163/320 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1296934945; called by muse, mutect2, varscan2
- F5 | c.5065G>T p.D1689Y | Missense Mutation (SNP) | VAF 129/303 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV63120589; called by muse, mutect2, varscan2
- F5 | c.3149C>T p.P1050L | Missense Mutation (SNP) | VAF 19/348 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.351); catalogued as rs761897827; called by muse, mutect2
- FAIM | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.991); catalogued as rs758050797, COSV58158526; called by muse, mutect2
- FAM47A | c.730G>T p.V244L | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.494); catalogued as COSV60494574, COSV60496410; called by muse, mutect2, varscan2
- FAM47C | c.1337G>C p.G446A | Missense Mutation (SNP) | VAF 127/223 reads (57%) | SIFT tolerated, low confidence (0.43); PolyPhen possibly damaging (0.57); catalogued as rs1287885089; called by muse, mutect2, varscan2
- FAT3 | c.4979C>A p.S1660Y | Missense Mutation (SNP) | VAF 95/200 reads (48%) | SIFT tolerated (1); PolyPhen probably damaging (0.983); catalogued as COSV53082047; called by muse, mutect2, varscan2
- FAT3 | c.5746C>A p.P1916T | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99970131; called by muse, mutect2, varscan2
- FAT4 | c.11819C>T p.S3940L | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs1342514440; called by muse, mutect2, varscan2
- FER1L5 | c.4915C>T p.R1639C (on ENST00000623019; = p.R1612C on NM_001293083.2) | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs752557299; called by muse, mutect2, varscan2
- FKBP1C | c.203G>T p.S68I | Missense Mutation (SNP) | VAF 213/392 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62179571; called by muse, mutect2, varscan2
- FLOT1 | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as rs955353053; called by muse, mutect2, varscan2
- FNDC1 | c.1170del p.V392* | Frame Shift Del (DEL) | VAF 51/113 reads (45%) | catalogued as COSV51947298; called by mutect2, pindel, varscan2
- FRMPD2 | c.683G>T p.C228F | Missense Mutation (SNP) | VAF 110/246 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0.321); catalogued as rs779793919; called by muse, mutect2, varscan2
- FZD2 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs530418343, COSV100190880; called by muse, mutect2, varscan2
- GDAP1L1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as rs771910437; called by muse, varscan2
- GHR | c.1234G>T p.A412S | Missense Mutation (SNP) | VAF 146/271 reads (54%) | SIFT tolerated (0.74); PolyPhen benign (0.19); catalogued as rs937887658; called by muse, mutect2, varscan2
- GHRHR | c.17G>T p.W6L | Missense Mutation (SNP) | VAF 200/515 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); catalogued as COSV58197785; called by muse, mutect2, varscan2
- GJA1 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 181/366 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV99246892; called by muse, mutect2, varscan2
- GLI3 | c.4292C>A p.P1431Q | Missense Mutation (SNP) | VAF 235/1299 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV67887381; called by muse, mutect2, varscan2
- GOLGA5 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV50832532; called by muse, mutect2, varscan2
- GPER1 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.527); catalogued as rs747835584, COSV52469213; called by muse, mutect2
- GPR149 | c.668C>A p.P223Q | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV67666988; called by muse, mutect2, varscan2
- GPR158 | c.2887C>T p.P963S | Missense Mutation (SNP) | VAF 37/490 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV66268265; called by muse, mutect2
- GPR85 | c.369del p.I123Mfs*11 | Frame Shift Del (DEL) | VAF 51/256 reads (20%) | catalogued as COSV51785122; called by mutect2, pindel, varscan2
- GPRIN2 | c.626G>A p.S209N | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.202); catalogued as rs782338642; called by muse, mutect2, varscan2
- GRID2IP | c.3282G>A p.V1094= | Splice Region (SNP) | VAF 39/179 reads (22%) | catalogued as COSV101474886; called by muse, mutect2, varscan2
- GRK7 | c.1064del p.G355Vfs*8 | Frame Shift Del (DEL) | VAF 29/79 reads (37%) | catalogued as COSV53823736; called by mutect2, pindel, varscan2
- GSC | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 115/439 reads (26%) | catalogued as rs1174607751, COSV53077298; called by muse, mutect2, varscan2
- H4C11 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100747954; called by muse, mutect2, varscan2
- H4C3 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 86/139 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as rs754919310; called by muse, varscan2
- HEPACAM | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.594); catalogued as rs571879332, COSV100005628, COSV100005724; called by muse, mutect2, varscan2
- HHLA2 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV63319320; called by muse, mutect2, varscan2
- HIVEP3 | c.5741G>A p.R1914Q | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs768586440; called by muse, mutect2
- HOXA5 | c.592G>C p.A198P | Missense Mutation (SNP) | VAF 95/213 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV56074309, COSV56075002; called by muse, mutect2, varscan2
- HSF1 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 62/256 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV100183907; called by muse, varscan2
- HSP90AA1 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 61/212 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs372198780; called by muse, mutect2, varscan2
- HTR7 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 56/365 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV53283822; called by muse, mutect2, varscan2
- IFNL2 | c.450G>T p.R150S | Missense Mutation (SNP) | VAF 94/207 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs1202694329, COSV59593536; called by muse, mutect2, varscan2
- IFT140 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.656); catalogued as COSV101276311; called by muse, mutect2, varscan2
- IGHV1-3 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 18/572 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as rs782144792; called by muse, mutect2
- IGHV3-20 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 98/351 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.286); catalogued as rs782058414; called by muse, mutect2, varscan2
- IGSF11 | c.1234G>T p.E412* (on ENST00000393775 / NM_001015887.3; = p.E411* on NM_152538.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 99/218 reads (45%) | catalogued as rs1345830252, COSV61178178; called by muse, mutect2, varscan2
- IL2 | c.331G>T p.V111L | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs756737575, COSV56985338, COSV56986744; called by muse, mutect2, varscan2
- INHA | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 72/151 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.036); catalogued as rs754673997; called by muse, mutect2, varscan2
- ITGA8 | c.938C>T p.T313M | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs774815440, COSV65234203; called by muse, mutect2, varscan2
- JAKMIP1 | c.564G>T p.Q188H | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.995); catalogued as rs750742115; called by muse, mutect2, varscan2
- KCNK10 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 62/274 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773338019, COSV56649528; called by muse, mutect2, varscan2
- KDM5C | c.263A>G p.Q88R | Missense Mutation (SNP) | VAF 112/216 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as rs1460418132; called by muse, mutect2, varscan2
- KIF19 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 23/236 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1377460311, COSV63429906; called by muse, mutect2
- KIF1B | c.2875G>C p.G959R (on ENST00000377086 / NM_001365952.1; = p.G913R on NM_015074.3) | Missense Mutation (SNP) | VAF 117/237 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV55805553, COSV99822699; called by muse, mutect2, varscan2
- KMT2A | c.3185C>T p.S1062F | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63281470, COSV63290009; called by muse, mutect2, varscan2
- KRT75 | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 67/124 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV52871736; called by muse, mutect2, varscan2
- KRTAP4-4 | c.305G>C p.R102P | Missense Mutation (SNP) | VAF 190/589 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV66811532; called by mutect2, varscan2
- LMAN1 | c.708G>C p.M236I | Missense Mutation (SNP) | VAF 45/273 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.083); catalogued as COSV99195322; called by muse, mutect2, varscan2
- LRRC4C | c.1717G>T p.D573Y | Missense Mutation (SNP) | VAF 71/263 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.836); catalogued as COSV53418562; called by muse, mutect2, varscan2
- LRRC9 | c.2632C>T p.H878Y | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1405884898; called by muse, mutect2, varscan2
- LTN1 | c.1844G>T p.R615M | Missense Mutation (SNP) | VAF 69/130 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100798043; called by muse, mutect2, varscan2
- MAST1 | c.1667C>A p.P556H | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52242664; called by muse, mutect2, varscan2
- MAST4 | c.6113C>T p.P2038L (on ENST00000403625 / NM_001164664.2; = p.P1849L on NM_015183.3) | Missense Mutation (SNP) | VAF 62/273 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as rs547744589; called by muse, mutect2, varscan2
- MCTP2 | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs202137443, COSV59148012; called by muse, mutect2, varscan2
- MED12 | c.4130C>T p.S1377F | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV61348767; called by muse, mutect2, varscan2
- MEOX1 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs192544910; called by muse, mutect2, varscan2
- MIER2 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1284249631, COSV99316343; called by muse, mutect2, varscan2
- MRE11 | c.652C>A p.Q218K | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60577273; called by muse, mutect2, varscan2
- MROH2B | c.4702G>A p.E1568K | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.962); catalogued as rs764758889, COSV68180610; called by muse, mutect2, varscan2
- MSH3 | c.1920G>T p.L640F | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as COSV54146539, COSV54160580; called by muse, mutect2, varscan2
- MYEF2 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 69/300 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs748577153, COSV51046080; called by muse, mutect2, varscan2
- N4BP1 | c.1169G>A p.R390K | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52210802; called by muse, mutect2, varscan2
- NELFB | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 90/325 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs754387255; called by muse, mutect2, varscan2
- NFE2L3 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV50236108; called by muse, mutect2, varscan2
- NKAPL | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 94/142 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV100642526; called by muse, mutect2, varscan2
- NKD2 | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV56890246; called by muse, mutect2, varscan2
- NOL4 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 89/260 reads (34%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.569); catalogued as COSV99307638; called by muse, mutect2, varscan2
- NUTM1 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as COSV100412074; called by muse, mutect2, varscan2
- OCSTAMP | c.1223T>A p.L408Q | Missense Mutation (SNP) | VAF 69/181 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54099661; called by muse, mutect2, varscan2
- ODAM | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770267053; called by muse, mutect2, varscan2
- OR10A5 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs747980262, COSV55056072; called by muse, mutect2, varscan2
- OR13C8 | c.267G>C p.K89N | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV100622984, COSV100623057; called by muse, mutect2, varscan2
- OR2L2 | c.523C>A p.H175N | Missense Mutation (SNP) | VAF 13/199 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs140243044, COSV63556417; called by muse, mutect2
- OR56A3 | c.225C>G p.I75M | Missense Mutation (SNP) | VAF 124/226 reads (55%) | SIFT tolerated (0.76); PolyPhen benign (0.046); catalogued as COSV100290210, COSV61570212; called by muse, mutect2, varscan2
- OR5P3 | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as COSV60430194; called by muse, mutect2, varscan2
- OR6B3 | c.970C>G p.L324V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.076); catalogued as COSV60116681; called by muse, mutect2, varscan2
- OR6C70 | c.432C>G p.F144L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59245004; called by muse, mutect2, varscan2
- OTOP1 | c.1579C>A p.P527T | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as rs538612026; called by muse, mutect2, varscan2
- OTUD7B | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 12/330 reads (4%) | catalogued as COSV100967282; called by muse, mutect2
- OVCH1 | c.2831C>A p.A944D | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs552476710; called by muse, mutect2, varscan2
- PAN2 | c.3553G>A p.E1185K (on ENST00000425394 / NM_001127460.3; = p.E1181K on NM_014871.5) | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV56263857; called by muse, mutect2, varscan2
- PAPPA2 | c.128T>A p.V43E | Missense Mutation (SNP) | VAF 159/308 reads (52%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.159); catalogued as COSV62784380; called by muse, mutect2, varscan2
- PCDH10 | c.332A>T p.E111V | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1386103376; called by muse, varscan2
- PCDHB9 | c.1525del p.D509Tfs*33 | Frame Shift Del (DEL) | VAF 179/574 reads (31%) | catalogued as COSV53379630, COSV53384818; called by mutect2, pindel, varscan2
- PCDHGA5 | c.769G>T p.V257L | Missense Mutation (SNP) | VAF 79/158 reads (50%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.029); catalogued as COSV54003907; called by muse, mutect2, varscan2
- PGLYRP3 | c.205G>T p.G69W | Missense Mutation (SNP) | VAF 210/632 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV51950874; called by muse, mutect2, varscan2
- PHACTR3 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs765373916; called by muse, mutect2, varscan2
- PIEZO2 | c.5305G>A p.E1769K | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.646); catalogued as rs1193696120; called by muse, mutect2, varscan2
- PLEC | c.8815G>T p.G2939C (on ENST00000322810 / NM_201380.4; = p.G2829C on NM_000445.5) | Missense Mutation (SNP) | VAF 81/301 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100520109; called by muse, mutect2, varscan2
- POLR2L | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV58990383, COSV58990492; called by muse, mutect2, varscan2
- POMGNT2 | c.1271G>T p.R424L | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as COSV100768127; called by muse, mutect2, varscan2
- POTEE | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 67/736 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.288); catalogued as COSV58229241; called by muse, mutect2
- PRPF3 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 50/412 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61396038; called by muse, mutect2, varscan2
- PRTFDC1 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs202058035; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.1188-3C>T | Splice Region (SNP) | VAF 41/186 reads (22%) | catalogued as rs923371834; called by muse, mutect2, varscan2
- PTPN3 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 18/279 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs529250315, COSV52701932; called by muse, mutect2
- RAD21 | c.1757G>A p.R586Q | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.979); catalogued as rs780692465, COSV52061251, COSV52061293; ClinVar: uncertain significance; called by muse, mutect2
- RB1 | c.2390T>A p.L797* | Nonsense Mutation (SNP) | VAF 88/196 reads (45%) | catalogued as CM023820, COSV57317102, COSV57328972; called by muse, mutect2, varscan2
- REG1A | c.64G>T p.G22C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52068316; called by muse, mutect2, varscan2
- RGPD8 | c.3268G>A p.E1090K | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.748); catalogued as rs1433301729, COSV100221976; called by mutect2, varscan2
- RGS3 | c.753G>A p.E251= (on ENST00000350696 / NM_001282923.2; = p.E139= on NM_017790.4) | Splice Region (SNP) | VAF 25/104 reads (24%) | catalogued as rs765116572; called by muse, mutect2, varscan2
- RNF149 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 103/393 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV54865204; called by muse, mutect2, varscan2
- RNF213 | c.11777C>G p.T3926S | Missense Mutation (SNP) | VAF 54/653 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.3); catalogued as rs373161624; called by muse, mutect2
- RNF43 | c.1820C>T p.S607L | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs200066146, COSV68456876; called by muse, mutect2, varscan2
- RPH3AL | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs946208917, COSV100046744; called by muse, mutect2, varscan2
- RTP5 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.587); catalogued as rs1447698598; called by muse, mutect2, varscan2
- RYR2 | c.9274C>T p.Q3092* | Nonsense Mutation (SNP) | VAF 128/349 reads (37%) | catalogued as COSV63698999, COSV63709440; called by muse, mutect2, varscan2
- SCARA5 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs1456191330; called by muse, mutect2, varscan2
- SCN8A | c.5894G>A p.R1965K | Missense Mutation (SNP) | VAF 163/489 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs188821990; called by muse, mutect2, varscan2
- SDC1 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.097); catalogued as COSV54338746; called by muse, mutect2, varscan2
- SEL1L2 | c.957C>T p.Y319= | Splice Region (SNP) | VAF 20/63 reads (32%) | catalogued as rs756636774, COSV53152177, COSV53159901; called by muse, mutect2, varscan2
- SERINC2 | c.1196C>T p.S399L (on ENST00000373709 / NM_178865.5; = p.S403L on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/218 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1553135080; called by muse, varscan2
- SF1 | c.1720C>T p.Q574* | Nonsense Mutation (SNP) | VAF 54/215 reads (25%) | catalogued as COSV99918083; called by muse, mutect2, varscan2
- SI | c.4790T>C p.M1597T | Missense Mutation (SNP) | VAF 88/252 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1191812834; called by muse, mutect2, varscan2
- SI | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52266275, COSV52273498; called by muse, mutect2, varscan2
- SLC43A2 | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 114/320 reads (36%) | catalogued as COSV100024624, COSV56770377; called by muse, mutect2, varscan2
- SLC45A4 | c.1727C>T p.S576L (on ENST00000517878 / NM_001286646.2; = p.S525L on NM_001080431.2) | Missense Mutation (SNP) | VAF 58/288 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs760978875; called by muse, mutect2, varscan2
- SLC4A8 | c.2365C>A p.P789T | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60649247; called by muse, mutect2, varscan2
- SLTM | c.2273G>A p.G758E | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV65850268; called by muse, mutect2, varscan2
- SLX4 | c.3761C>T p.S1254L | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750580998; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMS | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65113958; called by muse, mutect2, varscan2
- SMYD3 | c.688G>A p.E230K (on ENST00000490107 / NM_001375962.1; = p.E171K on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/550 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs147009044, COSV63629740; called by muse, mutect2
- SNRPN | c.217C>G p.R73G | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV57594900; called by muse, mutect2, varscan2
- SOX17 | c.735C>A p.C245* | Nonsense Mutation (SNP) | VAF 48/246 reads (20%) | catalogued as COSV52027838; called by muse, mutect2, varscan2
- SPEF2 | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 72/153 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs528000853; called by muse, mutect2, varscan2
- SPINK5 | c.2611C>T p.R871* | Nonsense Mutation (SNP) | VAF 46/393 reads (12%) | catalogued as rs1340491788, COSV56250215; called by muse, mutect2, varscan2
- SPZ1 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57063465; called by muse, mutect2, varscan2
- STAU2 | c.280A>G p.I94V (on ENST00000524300 / NM_001164380.2; = p.I62V on NM_014393.2) | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.074); catalogued as rs780931616; called by muse, mutect2, varscan2
- STK11 | c.458C>A p.A153D | Missense Mutation (SNP) | VAF 89/178 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1555737824; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STYXL2 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 357/669 reads (53%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.572); catalogued as COSV99068462; called by muse, mutect2, varscan2
- SULT1C2 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs868188082, COSV52266618; called by muse, mutect2, varscan2
- TASOR2 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755144615, COSV60165603; called by muse, mutect2, varscan2
- TCF20 | c.1906C>G p.Q636E | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.188); catalogued as COSV59490899; called by muse, mutect2
- TCN2 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs200868221, COSV53192149; called by muse, mutect2, varscan2
- TDRD10 | c.462G>C p.E154D | Missense Mutation (SNP) | VAF 28/279 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.432); catalogued as COSV63812101; called by muse, varscan2
- TENM3 | c.5247G>C p.W1749C | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV69312861; called by muse, mutect2, varscan2
- THEM6 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 70/305 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs1416684141; called by muse, mutect2, varscan2
- THSD7B | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1432017189, COSV55687904, COSV55747352; called by muse, mutect2, varscan2
- TM7SF2 | c.965G>A p.R322K | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV54206809; called by muse, mutect2, varscan2
- TMEM161B | c.1069A>G p.T357A | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.207); catalogued as rs1217472617, COSV56933343; called by muse, mutect2
- TRIM60 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.097); catalogued as COSV61970196; called by muse, mutect2, varscan2
- TSC22D3 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); catalogued as COSV59778897; called by muse, mutect2, varscan2
- TSEN34 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 103/408 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as rs769338809, COSV55477442; called by muse, mutect2, varscan2
- TSHZ3 | c.656G>C p.C219S | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53685092; called by muse, mutect2, varscan2
- TTN | c.102790G>A p.D34264N (on ENST00000591111; = p.D26840N on NM_003319.4) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | PolyPhen probably damaging (0.964); catalogued as COSV60360796; called by muse, mutect2
- TTN | c.79934G>A p.G26645E (on ENST00000591111; = p.G19221E on NM_003319.4) | Missense Mutation (SNP) | VAF 56/189 reads (30%) | PolyPhen probably damaging (1); catalogued as COSV60251098; called by muse, mutect2, varscan2
- USH1C | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 242/492 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs764346200; called by muse, mutect2, varscan2
- USH2A | c.3493G>A p.V1165M | Missense Mutation (SNP) | VAF 232/459 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV100231935; called by muse, mutect2, varscan2
- USP34 | c.433C>G p.P145A | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs767157179; called by muse, mutect2, varscan2
- VPS13B | c.5203G>T p.D1735Y | Missense Mutation (SNP) | VAF 149/396 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62152142; called by muse, mutect2, varscan2
- WDR17 | c.2497C>T p.Q833* | Nonsense Mutation (SNP) | VAF 18/81 reads (22%) | catalogued as COSV99708120; called by muse, mutect2, varscan2
- XPNPEP3 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs771709808; called by muse, mutect2, varscan2
- ZDHHC15 | c.135G>T p.L45= | Splice Region (SNP) | VAF 40/65 reads (62%) | catalogued as COSV100973855; called by muse, varscan2
- ZFC3H1 | c.5053C>T p.R1685* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as COSV101110371; called by muse, mutect2, varscan2
- ZFHX4 | c.8855G>A p.R2952Q | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51452712; called by muse, mutect2, varscan2
- ZNF250 | c.399G>C p.L133F | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.467); catalogued as rs1179982924; called by muse, mutect2, varscan2
- ZNF528 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1334034062, COSV64618868; called by muse, mutect2, varscan2
- ZNF584 | c.964G>C p.G322R | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100183234; called by muse, mutect2, varscan2
- ZNF671 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 36/135 reads (27%) | catalogued as rs372532500; called by muse, mutect2, varscan2
- ZNF730 | c.1331G>C p.R444T | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.132); catalogued as COSV74168152; called by muse, mutect2, varscan2
- ZNF804A | c.2929G>A p.E977K | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV56433696; called by muse, mutect2
- ZPLD1 | c.518C>T p.A173V (on ENST00000466937 / NM_001329788.1; = p.A189V on NM_175056.2) | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.398); catalogued as rs202040687, COSV60355789; called by muse, mutect2, varscan2
- A2M | c.87del p.Q30Sfs*22 | Frame Shift Del (DEL) | VAF 42/101 reads (42%) | called by mutect2, pindel, varscan2
- ABCF2 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 29/174 reads (17%) | called by muse, mutect2, varscan2
- ABLIM1 | c.972G>A p.M324I | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- ACBD3 | c.759G>C p.Q253H | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ACOXL | c.1051G>A p.G351R | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACTL6A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 40/364 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ADAL | c.788C>G p.S263* (on ENST00000562188 / NM_001324366.2; = p.S236* on NM_001159280.3) | Nonsense Mutation (SNP) | VAF 46/161 reads (29%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.63+1G>C p.X21_splice | Splice Site (SNP) | VAF 68/142 reads (48%) | called by muse, mutect2, varscan2
- ADCYAP1 | c.301G>C p.A101P | Missense Mutation (SNP) | VAF 77/249 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AGGF1 | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 54/294 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AGXT2 | c.1191G>C p.V397= | Splice Region (SNP) | VAF 119/407 reads (29%) | called by muse, mutect2, varscan2
- AKR1C2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ALMS1 | c.9421G>C p.D3141H | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ALPP | c.402G>C p.L134F | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- ANGPT4 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.022); called by muse, mutect2
- ANKAR | c.3076C>G p.Q1026E | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ANTXRL | c.1616A>T p.H539L | Missense Mutation (SNP) | VAF 88/345 reads (26%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- AP3B2 | c.836G>A p.G279D | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- APOB | c.8626A>G p.K2876E | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.435); called by muse, mutect2
- APOL6 | c.120A>C p.K40N | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- ARAP3 | c.1014G>T p.E338D | Missense Mutation (SNP) | VAF 75/197 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- ARL4D | c.484C>G p.L162V | Missense Mutation (SNP) | VAF 138/494 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.309); called by muse, varscan2
- ARMCX1 | c.338A>G p.N113S | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARMCX1 | c.775A>G p.K259E | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ASTN2 | c.2075C>G p.S692C (on ENST00000313400 / NM_001365069.1; = p.S641C on NM_014010.5) | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- ATG16L1 | c.1633G>A p.D545N (on ENST00000392017 / NM_030803.7; = p.D526N on NM_017974.4) | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATG4D | c.145C>G p.L49V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, varscan2
- ATP13A2 | c.1915G>C p.V639L | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BCL11A | c.1972T>A p.S658T (on ENST00000335712 / NM_001365609.1; = p.S692T on NM_018014.4) | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- BEND6 | c.5A>T p.Q2L | Missense Mutation (SNP) | VAF 73/149 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- BLMH | c.1176G>T p.W392C | Missense Mutation (SNP) | VAF 98/296 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BPIFB3 | c.1184C>A p.A395D | Missense Mutation (SNP) | VAF 79/347 reads (23%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- C22orf39 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 62/283 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- C2orf74 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, varscan2
- C2orf74 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.084); called by muse, varscan2
- CACNA1D | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- CACNG8 | c.1169C>G p.P390R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASP8AP2 | c.3516G>C p.Q1172H | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- CASP8AP2 | c.4024G>A p.E1342K | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CASP8AP2 | c.4276G>C p.E1426Q | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- CATSPER1 | c.1759C>T p.L587F | Missense Mutation (SNP) | VAF 113/219 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CBX3 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CC2D2A | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- CCDC7 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CCNO | c.626C>A p.S209Y | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- CD300E | c.422C>A p.A141D | Missense Mutation (SNP) | VAF 70/367 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDAN1 | c.3500T>A p.M1167K | Missense Mutation (SNP) | VAF 115/541 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CDKAL1 | c.1740G>C p.*580Yext*16 | Nonstop Mutation (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
- CELF2 | c.664C>T p.Q222* (on ENST00000416382 / NM_001025077.3; = p.Q229* on NM_006561.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2, varscan2
- CFAP54 | c.300C>G p.H100Q | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2
- CFAP74 | c.2434A>T p.K812* | Nonsense Mutation (SNP) | VAF 86/195 reads (44%) | called by muse, mutect2, varscan2
- CHAT | c.1921A>C p.M641L | Missense Mutation (SNP) | VAF 340/837 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CHGB | c.125C>G p.S42* | Nonsense Mutation (SNP) | VAF 74/411 reads (18%) | called by muse, mutect2, varscan2
- CHP1 | c.310G>C p.G104R | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.013); called by muse, mutect2
- CHRFAM7A | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.026); called by mutect2, varscan2
- CHRM2 | c.535C>G p.Q179E | Missense Mutation (SNP) | VAF 151/389 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CHRNA5 | c.222A>G p.I74M | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- CIAO1 | c.900G>T p.Q300H | Missense Mutation (SNP) | VAF 246/651 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- CLPSL1 | c.341A>C p.K114T | Missense Mutation (SNP) | VAF 252/483 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CMTM2 | c.337A>G p.I113V | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CNOT4 | c.1438C>T p.Q480* (on ENST00000315544 / NM_001190848.1; = p.Q477* on NM_013316.4) | Nonsense Mutation (SNP) | VAF 48/252 reads (19%) | called by muse, mutect2, varscan2
- COG7 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.183); called by muse, varscan2
- COL3A1 | c.2548C>G p.P850A | Missense Mutation (SNP) | VAF 121/318 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- COL3A1 | c.3754G>T p.D1252Y | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- COL5A1 | c.1460G>T p.G487V | Missense Mutation (SNP) | VAF 138/267 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A3 | c.7770C>G p.I2590M | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- COQ8B | c.985G>T p.G329W | Missense Mutation (SNP) | VAF 136/285 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.10628-1G>T p.X3543_splice (on ENST00000297405 / NM_001363185.1; = p.X3374_splice on NM_052900.3) | Splice Site (SNP) | VAF 94/300 reads (31%) | called by muse, mutect2, varscan2
- CSMD3 | c.6442+1G>A p.X2148_splice (on ENST00000297405 / NM_001363185.1; = p.X2044_splice on NM_052900.3) | Splice Site (SNP) | VAF 67/240 reads (28%) | called by muse, mutect2, varscan2
- CTNNA1 | c.1320C>G p.I440M | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CTNND1 | c.2548C>T p.Q850* (on ENST00000399050 / NM_001085458.2; = p.Q844* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2
- CYP17A1 | c.1413del p.Q472Sfs*14 | Frame Shift Del (DEL) | VAF 129/557 reads (23%) | called by mutect2, pindel, varscan2
- CYP2A7P2 | n.466C>A | Splice Region (SNP) | VAF 39/178 reads (22%) | called by muse, mutect2, varscan2
- DAPK1 | c.12C>G p.F4L | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, varscan2
- DCX | c.970C>A p.L324I (on ENST00000636035 / NM_001195553.2; = p.L319I on NM_000555.3) | Missense Mutation (SNP) | VAF 75/146 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- DDX24 | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 49/238 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- DEPDC5 | c.3485C>A p.T1162K (on ENST00000400246; = p.T1231K on NM_014662.5) | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.93); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- DHRS12 | c.530G>T p.G177V (on ENST00000444610 / NM_001377930.1; = p.G128V on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/145 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAJB4 | c.10G>C p.D4H | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DNAJC28 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNASE2 | c.1067G>A p.R356K | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK8 | c.3925C>A p.Q1309K | Missense Mutation (SNP) | VAF 83/263 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DPP10 | c.428A>G p.Y143C | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- DPY19L3 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DPYSL3 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 37/288 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- DRD2 | c.859A>G p.T287A | Missense Mutation (SNP) | VAF 79/151 reads (52%) | SIFT tolerated (0.97); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DROSHA | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2
- DTX3 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DUOX1 | c.1387A>T p.T463S | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- EDN3 | c.427G>T p.G143W | Missense Mutation (SNP) | VAF 92/423 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- EEF1AKMT2 | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 97/446 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ELMO3 | c.254C>T p.A85V (on ENST00000652269; = p.A32V on NM_024712.5) | Missense Mutation (SNP) | VAF 59/241 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- ELP6 | c.623T>G p.L208R | Missense Mutation (SNP) | VAF 119/421 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ENAH | c.1543G>T p.D515Y | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2
- EPS15L1 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERC2 | c.2274G>C p.M758I | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- ERV3-1 | c.1046G>T p.W349L | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXOSC1 | c.126G>T p.M42I | Missense Mutation (SNP) | VAF 68/230 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, varscan2
- F2R | c.638G>A p.W213* | Nonsense Mutation (SNP) | VAF 323/913 reads (35%) | called by muse, mutect2, varscan2
- FAM110B | c.940A>T p.I314F | Missense Mutation (SNP) | VAF 47/266 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- FAR2 | c.506C>G p.P169R | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FBXO38 | c.289C>A p.L97I | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FCN2 | c.504T>A p.S168R | Missense Mutation (SNP) | VAF 63/134 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- FER1L6 | c.3760C>A p.P1254T | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FSCN2 | c.505T>A p.W169R | Missense Mutation (SNP) | VAF 220/620 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSCN2 | c.506G>A p.W169* | Nonsense Mutation (SNP) | VAF 219/613 reads (36%) | called by muse, mutect2, varscan2
- FSD2 | c.1280C>A p.T427N | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FUCA1 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GABRA5 | c.1319T>A p.F440Y | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRB3 | c.1092T>A p.H364Q | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GANC | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 11/120 reads (9%) | called by muse, mutect2
- GAREM1 | c.2232G>T p.L744F (on ENST00000269209 / NM_001242409.2; = p.L743F on NM_022751.3) | Missense Mutation (SNP) | VAF 66/151 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GAREM2 | c.544G>T p.G182W | Missense Mutation (SNP) | VAF 20/343 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- GATAD1 | c.268A>T p.R90W | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GDE1 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- GFM2 | c.2138G>A p.G713E | Missense Mutation (SNP) | VAF 57/321 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GLI2 | c.2878G>A p.D960N (on ENST00000361492 / NM_001374353.1; = p.D977N on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/516 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- GPR141 | c.770C>A p.A257D | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPRC5A | c.982-3C>G | Splice Region (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- GRAMD2A | c.524G>C p.R175T | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIA4 | c.310del p.H104Ifs*3 | Frame Shift Del (DEL) | VAF 44/350 reads (13%) | called by mutect2, pindel, varscan2
- GRIN1 | c.2267C>T p.S756L | Missense Mutation (SNP) | VAF 109/421 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GTPBP3 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HACD2 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 34/251 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- HCN1 | c.2132C>A p.P711H | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- HDHD2 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2
- HECTD2 | c.1179A>G p.I393M | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- HLA-G | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 128/586 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); called by muse, varscan2
- HMCN1 | c.12823G>A p.E4275K | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2
- HOXA1 | c.649A>T p.T217S | Missense Mutation (SNP) | VAF 137/379 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- HRNR | c.593G>C p.G198A | Missense Mutation (SNP) | VAF 144/373 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IL1RAPL2 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INPPL1 | c.3292C>T p.P1098S | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- IQCA1 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- IQCB1 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 86/199 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- IRF9 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ITPRIP | c.759G>C p.L253F | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ITPRIPL1 | c.551C>A p.P184H (on ENST00000439118 / NM_001008949.3; = p.P192H on NM_178495.6) | Missense Mutation (SNP) | VAF 93/249 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- JMJD4 | c.698C>A p.P233Q | Missense Mutation (SNP) | VAF 300/525 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNA4 | c.1405C>A p.H469N | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KCNS1 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KCNT2 | c.2756C>T p.T919I | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KCTD13 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KDF1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 47/254 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- KDM1A | c.2360C>T p.P787L | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); called by muse, mutect2
- KDM4E | c.809T>C p.V270A | Missense Mutation (SNP) | VAF 15/315 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KDM5C | c.883_892del p.K295* | Frame Shift Del (DEL) | VAF 65/130 reads (50%) | called by mutect2, pindel, varscan2
- KIAA0825 | c.2774G>A p.R925K | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA1143 | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1586 | c.2265G>A p.W755* | Nonsense Mutation (SNP) | VAF 30/126 reads (24%) | called by muse, mutect2, varscan2
- KIF16B | c.2105_2108dup p.R704Sfs*20 | Frame Shift Ins (INS) | VAF 46/364 reads (13%) | called by mutect2, pindel
- KIFC3 | c.1597G>T p.G533C | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHDC7B | c.918G>T p.E306D (on ENST00000395676; = p.E947D on NM_138433.5) | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHDC7B | c.919G>T p.E307* (on ENST00000395676; = p.E948* on NM_138433.5) | Nonsense Mutation (SNP) | VAF 16/127 reads (13%) | called by muse, mutect2, varscan2
- KLHL4 | c.1356del p.T453Pfs*10 | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | called by mutect2, pindel
- KNL1 | c.5877-1G>C p.X1959_splice (on ENST00000346991 / NM_170589.5; = p.X1933_splice on NM_144508.5) | Splice Site (SNP) | VAF 11/75 reads (15%) | called by muse, mutect2, varscan2
- KRTAP13-3 | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 63/211 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- LAMA2 | c.5221G>A p.E1741K | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.254); called by muse, varscan2
- LARS2 | c.1106C>G p.S369C | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LCE2C | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 54/612 reads (9%) | called by muse, mutect2
- LGR4 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LIFR | c.1607C>T p.S536L | Missense Mutation (SNP) | VAF 33/388 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.471); called by muse, mutect2
- LILRA1 | c.1175C>G p.S392W | Missense Mutation (SNP) | VAF 170/662 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LOXHD1 | c.4939G>A p.A1647T | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- LPIN2 | c.1067C>A p.S356* | Nonsense Mutation (SNP) | VAF 69/284 reads (24%) | called by muse, mutect2, varscan2
- LRBA | c.6678G>C p.L2226F | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRGUK | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- LRRTM4 | c.1024C>A p.P342T | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LYST | c.2949G>T p.R983S | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LYST | c.2948G>T p.R983M | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- MAGEA8 | c.390G>T p.K130N | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MAL2 | c.500dup p.L167Ffs*55 | Frame Shift Ins (INS) | VAF 37/188 reads (20%) | called by mutect2, pindel, varscan2
- MALRD1 | c.5357G>T p.G1786V | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- MAOB | c.590G>C p.R197T | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- MAOB | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, varscan2
- MARCHF6 | c.2713C>T p.P905S | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- MAS1L | c.543C>A p.Y181* | Nonsense Mutation (SNP) | VAF 168/251 reads (67%) | called by muse, mutect2, varscan2
- MDGA2 | c.2748T>A p.H916Q (on ENST00000399232 / NM_001113498.2; = p.H618Q on NM_182830.4) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MDGA2 | c.955G>A p.D319N (on ENST00000399232 / NM_001113498.2; = p.D21N on NM_182830.4) | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MGAM2 | c.5269G>T p.G1757C | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MLH3 | c.1108G>A p.G370S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MMP16 | c.181T>C p.S61P | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- MMP27 | c.528G>T p.L176F | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- MMRN2 | c.164+1G>A p.X55_splice | Splice Site (SNP) | VAF 52/400 reads (13%) | called by muse, mutect2
- MROH8 | c.781G>C p.G261R | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MSANTD1 | c.394C>G p.L132V | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MSC | c.310T>A p.C104S | Missense Mutation (SNP) | VAF 120/374 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- MTMR8 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- MTOR | c.7453G>C p.D2485H | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- MTRR | c.643G>A p.E215K (on ENST00000264668; = p.E188K on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/323 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MYH11 | c.2521-1G>A p.X841_splice | Splice Site (SNP) | VAF 109/540 reads (20%) | called by muse, mutect2, varscan2
- MYT1 | c.2558G>A p.G853D | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCKAP5 | c.2755G>T p.G919W | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- NCOA2 | c.1003C>G p.Q335E | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NEB | c.5086A>T p.I1696L | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- NLRP11 | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 85/186 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NPC2 | c.448C>G p.H150D | Missense Mutation (SNP) | VAF 112/388 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NR1H4 | c.527G>T p.G176V (on ENST00000551379 / NM_001206993.2; = p.G166V on NM_005123.4) | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRAP | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 41/117 reads (35%) | called by muse, mutect2, varscan2
- NRK | c.4219G>A p.D1407N | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- NRROS | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NRXN3 | c.994C>A p.P332T | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NTSR2 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NUDT6 | c.938A>T p.K313I | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUP133 | c.2211G>T p.Q737H | Missense Mutation (SNP) | VAF 153/280 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OLFM1 | c.965G>A p.R322K (on ENST00000371793 / NM_001282611.2; = p.R304K on NM_014279.5) | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT tolerated (0.95); PolyPhen benign (0.001); called by muse, mutect2
- OR10T2 | c.553G>T p.V185F | Missense Mutation (SNP) | VAF 61/112 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR2A12 | c.558G>T p.L186F | Missense Mutation (SNP) | VAF 86/457 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2H1 | c.534G>T p.E178D | Missense Mutation (SNP) | VAF 163/288 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- OR2M7 | c.174del p.M59Cfs*72 | Frame Shift Del (DEL) | VAF 64/196 reads (33%) | called by mutect2, pindel, varscan2
- OR51D1 | c.773T>A p.L258H | Missense Mutation (SNP) | VAF 129/261 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR51M1 | c.206C>A p.T69K | Missense Mutation (SNP) | VAF 133/296 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- OR51V1 | c.685C>A p.L229M | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- OR5H1 | c.628A>T p.S210C | Missense Mutation (SNP) | VAF 81/200 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- OR6C70 | c.152C>G p.S51C | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- OR6P1 | c.942T>A p.D314E | Missense Mutation (SNP) | VAF 110/190 reads (58%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- OSBPL6 | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- OSMR | c.881G>T p.C294F | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- OTOF | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 167/339 reads (49%) | called by muse, mutect2, varscan2
- PABPC1L2A | c.71C>A p.P24Q | Missense Mutation (SNP) | VAF 70/268 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.039); called by muse, varscan2
- PACSIN2 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 12/324 reads (4%) | called by muse, mutect2
- PAPLN | c.1759G>A p.D587N (on ENST00000554301; = p.D560N on NM_173462.4) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAPPA2 | c.3515G>C p.R1172T | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- PATE1 | c.341G>A p.R114K | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PAX6 | c.396C>A p.S132R | Missense Mutation (SNP) | VAF 324/637 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- PCDH10 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); called by muse, varscan2
- PCDHGA2 | c.1240C>G p.Q414E | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PCLO | c.2611A>G p.M871V | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCLO | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- PCNX2 | c.1138A>T p.M380L | Missense Mutation (SNP) | VAF 23/257 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.813); called by muse, mutect2
- PDZRN4 | c.1673C>A p.T558K (on ENST00000402685 / NM_001164595.2; = p.T300K on NM_013377.4) | Missense Mutation (SNP) | VAF 128/249 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- PFKFB3 | c.1350G>C p.K450N | Missense Mutation (SNP) | VAF 37/117 reads (32%) | PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PGM5 | c.1044-1G>C p.X348_splice | Splice Site (SNP) | VAF 20/83 reads (24%) | called by muse, mutect2, varscan2
- PHGDH | c.1457C>T p.S486F | Missense Mutation (SNP) | VAF 32/540 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.692); called by muse, mutect2
- PHKG1 | c.10G>T p.D4Y | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PIEZO2 | c.6732G>T p.M2244I | Missense Mutation (SNP) | VAF 114/500 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- PIWIL1 | c.445C>T p.L149F | Missense Mutation (SNP) | VAF 138/288 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCB4 | c.2528C>T p.S843L | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2
- PLCG1 | c.370+1G>T p.X124_splice | Splice Site (SNP) | VAF 10/167 reads (6%) | called by muse, mutect2
- PLEKHB2 | c.919G>T p.A307S | Missense Mutation (SNP) | VAF 34/152 reads (22%) | PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- PLPP7 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.61); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PNLIP | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 39/162 reads (24%) | called by muse, mutect2, varscan2
- POLA1 | c.2284C>G p.L762V | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLE4 | c.192C>G p.I64M | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- POTEF | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 42/394 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.288); called by mutect2, varscan2
- POTEJ | c.980A>G p.Q327R | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- POU3F3 | c.246G>T p.M82I | Missense Mutation (SNP) | VAF 98/253 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.107); called by muse, varscan2
- PPEF2 | c.379C>T p.H127Y | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PPFIA2 | c.3767C>T p.S1256L | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- PPWD1 | c.1860G>C p.Q620H | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- PRDM5 | c.651-2A>G p.X217_splice | Splice Site (SNP) | VAF 32/221 reads (14%) | called by muse, mutect2, varscan2
- PRRC2A | c.5803C>T p.P1935S | Missense Mutation (SNP) | VAF 53/273 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- PRUNE2 | c.6664G>A p.D2222N | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- PRXL2A | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 26/78 reads (33%) | called by muse, mutect2, varscan2
- PTGR2 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRB | c.3091C>G p.L1031V | Missense Mutation (SNP) | VAF 88/260 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPRM | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PZP | c.294G>T p.E98D | Missense Mutation (SNP) | VAF 63/118 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- R3HDM2 | c.530A>T p.Q177L | Missense Mutation (SNP) | VAF 57/100 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- RAD51AP1 | c.702G>C p.K234N (on ENST00000228843 / NM_001130862.2; = p.K217N on NM_006479.5) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- RASSF2 | c.959C>A p.A320D | Missense Mutation (SNP) | VAF 101/292 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- RC3H1 | c.2864G>T p.G955V | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- RECQL4 | c.2917C>G p.Q973E | Missense Mutation (SNP) | VAF 18/437 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.062); called by muse, mutect2
- RGS20 | c.968C>T p.S323F (on ENST00000297313 / NM_170587.4; = p.S176F on NM_003702.4) | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RHOJ | c.82G>T p.G28W | Missense Mutation (SNP) | VAF 71/275 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RP1L1 | c.6065G>T p.G2022V | Missense Mutation (SNP) | VAF 118/374 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- RPLP0 | c.42_45del p.F14Lfs*40 | Frame Shift Del (DEL) | VAF 26/144 reads (18%) | called by mutect2, pindel, varscan2
- RPRD1B | c.282-1G>C p.X94_splice | Splice Site (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- RSPRY1 | c.1052G>T p.R351L | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- RTL1 | c.35T>C p.M12T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- RUFY2 | c.1826C>G p.S609C | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RYR2 | c.8064G>A p.M2688I | Missense Mutation (SNP) | VAF 99/252 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- RYR3 | c.1187C>A p.T396K | Missense Mutation (SNP) | VAF 60/220 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- SAMM50 | c.750C>G p.S250R | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SARS1 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEC31B | c.1969G>T p.E657* | Nonsense Mutation (SNP) | VAF 72/189 reads (38%) | called by muse, mutect2, varscan2
- SERPINB2 | c.1024G>T p.G342W | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEZ6L | c.460C>A p.L154I | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SHISA9 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 80/286 reads (28%) | called by muse, mutect2, varscan2
- SIPA1 | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 83/318 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- SIPA1L1 | c.5068G>A p.E1690K | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SIPA1L3 | c.3347del p.Q1116Rfs*4 | Frame Shift Del (DEL) | VAF 101/225 reads (45%) | called by mutect2, pindel, varscan2
- SIX5 | c.1465C>T p.Q489* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- SLC15A4 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 39/341 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC38A8 | c.1212C>T p.V404= | Splice Region (SNP) | VAF 36/95 reads (38%) | called by muse, mutect2, varscan2
- SLC45A4 | c.640G>T p.G214C (on ENST00000517878 / NM_001286646.2; = p.G163C on NM_001080431.2) | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SLC4A2 | c.1360C>T p.H454Y | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SLIT2 | c.1045T>A p.S349T | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- SLIT2 | c.1109G>T p.G370V | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLIT2 | c.1353G>C p.E451D | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SLITRK2 | c.1792A>G p.T598A | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNRNP40 | c.651C>G p.I217M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- SNTG1 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 59/180 reads (33%) | called by muse, mutect2, varscan2
- SOS2 | c.179G>T p.C60F | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SPARC | c.858G>T p.W286C | Missense Mutation (SNP) | VAF 101/183 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPTAN1 | c.5455G>T p.A1819S | Missense Mutation (SNP) | VAF 358/651 reads (55%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SPTBN5 | c.2872G>A p.E958K | Missense Mutation (SNP) | VAF 34/326 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.903); called by muse, mutect2
- SRCAP | c.8873G>A p.G2958E | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- SREK1 | c.-178+5G>C | Splice Region (SNP) | VAF 119/457 reads (26%) | called by muse, mutect2, varscan2
- SRGAP2 | c.829G>C p.D277H | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- SSX3 | c.416T>G p.L139R | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- ST8SIA6 | c.986G>A p.S329N | Missense Mutation (SNP) | VAF 81/457 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- STK17A | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- STRIP2 | c.2254+3G>C | Splice Region (SNP) | VAF 32/151 reads (21%) | called by muse, mutect2, varscan2
- SUGP1 | c.1244-1G>T p.X415_splice | Splice Site (SNP) | VAF 179/230 reads (78%) | called by muse, mutect2, varscan2
- SUPT5H | c.1564dup p.S522Ffs*14 | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | called by mutect2, varscan2
- SUPT5H | c.1565delinsTA p.S522Lfs*14 | Frame Shift Ins (INS) | VAF 9/50 reads (18%) | called by mutect2*, pindel, varscan2*
- SUSD5 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- SYNE1 | c.23142C>A p.C7714* (on ENST00000367255 / NM_182961.4; = p.C7643* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 122/247 reads (49%) | called by muse, mutect2, varscan2
- SYNM | c.1153C>T p.Q385* | Nonsense Mutation (SNP) | VAF 66/534 reads (12%) | called by muse, mutect2, varscan2
- TAF6 | c.1211G>T p.R404L | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TANGO2 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TASOR2 | c.872C>G p.S291* | Nonsense Mutation (SNP) | VAF 40/249 reads (16%) | called by muse, mutect2, varscan2
- TENM3 | c.1439C>G p.A480G | Missense Mutation (SNP) | VAF 49/326 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, varscan2
- TEX13C | c.1219C>A p.H407N | Missense Mutation (SNP) | VAF 103/216 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TEX15 | c.7414G>T p.D2472Y (on ENST00000256246; = p.D2855Y on NM_001350162.2) | Missense Mutation (SNP) | VAF 74/168 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- TG | c.7537G>T p.D2513Y | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- TGFB1 | c.1014G>T p.K338N | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TLR9 | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- TMEM170A | c.208C>T p.L70F | Missense Mutation (SNP) | VAF 54/308 reads (18%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- TMEM80 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 95/365 reads (26%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- TMEM94 | c.491C>G p.S164C | Missense Mutation (SNP) | VAF 144/410 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TNS2 | c.569C>G p.P190R (on ENST00000314250 / NM_170754.4; = p.P200R on NM_015319.2) | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TOPORS | c.932A>T p.H311L | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2
- TRIM37 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TRIM66 | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 90/293 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- TRIM8 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 78/146 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- TRPM8 | c.2459C>G p.S820C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- TTN | c.90140T>A p.L30047* (on ENST00000591111; = p.L22623* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
- TUFM | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 125/462 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- UBAP2L | c.1132C>G p.Q378E | Missense Mutation (SNP) | VAF 123/529 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- URGCP | c.532G>A p.D178N (on ENST00000453200 / NM_001077663.3; = p.D169N on NM_017920.4) | Missense Mutation (SNP) | VAF 84/330 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- USH1G | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 51/491 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- USP19 | c.2391G>T p.K797N | Missense Mutation (SNP) | VAF 108/274 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- USP37 | c.2668C>T p.R890W | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- UTRN | c.9181G>A p.A3061T | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- VAX1 | c.24G>T p.M8I | Missense Mutation (SNP) | VAF 80/434 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- VOPP1 | c.192G>C p.W64C | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- VPS16 | c.1069G>C p.E357Q | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- VWF | c.7684C>A p.Q2562K | Missense Mutation (SNP) | VAF 41/270 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ZDBF2 | c.5500C>T p.Q1834* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- ZFHX3 | c.952A>T p.S318C | Missense Mutation (SNP) | VAF 87/181 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ZFHX4 | c.6763G>A p.E2255K | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZNF208 | c.1313C>G p.S438* | Nonsense Mutation (SNP) | VAF 78/333 reads (23%) | called by muse, mutect2, varscan2
- ZNF292 | c.7642del p.E2548Kfs*11 | Frame Shift Del (DEL) | VAF 40/164 reads (24%) | called by mutect2, pindel, varscan2
- ZNF324B | c.855C>A p.Y285* | Nonsense Mutation (SNP) | VAF 67/391 reads (17%) | called by muse, mutect2, varscan2
- ZNF469 | c.9469G>T p.A3157S (on ENST00000437464; = p.A3185S on NM_001367624.2) | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- ZNF497 | c.20G>A p.W7* | Nonsense Mutation (SNP) | VAF 10/15 reads (67%) | called by muse, mutect2, varscan2
- ZNF521 | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 72/160 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- ZNF528 | c.823G>C p.D275H | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- ZNF585B | c.713G>A p.G238E | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF710 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF721 | c.1699C>T p.H567Y (on ENST00000338977; = p.H579Y on NM_133474.4) | Missense Mutation (SNP) | VAF 96/297 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ZNF735 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 62/338 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZSCAN1 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 242/585 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC139530.2 | c.435G>A p.L145= | Silent (SNP) | VAF 31/303 reads (10%) | catalogued as rs1045443717; called by muse, mutect2, varscan2
- ACKR2 | c.876C>T p.Y292= | Silent (SNP) | VAF 27/273 reads (10%) | catalogued as rs547304854, COSV56177899; called by muse, mutect2, varscan2
- ADAM32 | c.1338A>T p.S446= | Silent (SNP) | VAF 48/253 reads (19%) | catalogued as COSV101165309; called by muse, mutect2, varscan2
- ADAMTS18 | c.810T>C p.Y270= | Silent (SNP) | VAF 74/192 reads (39%) | called by muse, mutect2, varscan2
- ADPRH | c.405C>A p.A135= | Silent (SNP) | VAF 20/662 reads (3%) | called by muse, mutect2
- ADRA1D | c.1392C>T p.L464= | Silent (SNP) | VAF 45/175 reads (26%) | called by muse, mutect2, varscan2
- AHNAK | c.8337C>T p.F2779= | Silent (SNP) | VAF 91/356 reads (26%) | catalogued as rs754508241; called by muse, mutect2, varscan2
- AIPL1 | c.288C>T p.V96= | Silent (SNP) | VAF 108/268 reads (40%) | called by muse, mutect2
- ANK1 | c.4458C>T p.S1486= | Silent (SNP) | VAF 267/843 reads (32%) | catalogued as rs200752263; called by muse, mutect2, varscan2
- AP4M1 | c.1276C>T p.L426= | Silent (SNP) | VAF 150/884 reads (17%) | catalogued as COSV100384928; called by muse, mutect2, varscan2
- APOB | c.10203G>A p.L3401= | Silent (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2, varscan2
- APOB | c.9201G>A p.K3067= | Silent (SNP) | VAF 34/104 reads (33%) | called by muse, mutect2, varscan2
- AQP3 | c.396C>T p.D132= | Silent (SNP) | VAF 190/377 reads (50%) | called by muse, mutect2, varscan2
- ARHGEF2 | c.1191C>G p.L397= (on ENST00000361247 / NM_001162383.2; = p.L369= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 32/531 reads (6%) | called by muse, mutect2
- ARMH3 | c.864G>A p.E288= | Silent (SNP) | VAF 31/136 reads (23%) | called by muse, mutect2, varscan2
- ARRDC4 | c.33G>T p.V11= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as rs1276273368; called by muse, varscan2
- ASAP1 | c.2211G>A p.Q737= | Silent (SNP) | VAF 46/265 reads (17%) | called by muse, mutect2, varscan2
- ASB18 | c.54G>A p.K18= | Silent (SNP) | VAF 19/209 reads (9%) | catalogued as COSV101293591; called by muse, mutect2
- ASCC3 | c.3498G>A p.V1166= | Silent (SNP) | VAF 30/208 reads (14%) | called by muse, mutect2, varscan2
- BRPF1 | c.1869G>A p.Q623= | Silent (SNP) | VAF 41/122 reads (34%) | called by muse, mutect2, varscan2
- C3 | c.2580C>T p.L860= | Silent (SNP) | VAF 138/561 reads (25%) | called by muse, mutect2, varscan2
- CAND2 | c.2026C>T p.L676= (on ENST00000456430 / NM_001162499.2; = p.L583= on NM_012298.3) | Silent (SNP) | VAF 34/231 reads (15%) | called by muse, mutect2, varscan2
- CAPN8 | c.1923C>T p.L641= | Silent (SNP) | VAF 98/238 reads (41%) | called by muse, mutect2, varscan2
- CCT8L2 | c.990G>A p.L330= | Silent (SNP) | VAF 56/393 reads (14%) | catalogued as COSV63462509; called by muse, mutect2, varscan2
- CD5L | c.270C>T p.L90= | Silent (SNP) | VAF 68/544 reads (13%) | catalogued as rs1188283058, COSV63822738; called by muse, mutect2, varscan2
- CDH8 | c.2088C>T p.P696= | Silent (SNP) | VAF 66/216 reads (31%) | catalogued as COSV100180426; called by muse, mutect2, varscan2
- CDT1 | c.12C>A p.R4= | Silent (SNP) | VAF 163/419 reads (39%) | called by muse, mutect2, varscan2
- CELF2 | c.663C>T p.L221= (on ENST00000416382 / NM_001025077.3; = p.L228= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/62 reads (23%) | called by muse, mutect2, varscan2
- CFAP43 | c.1722G>A p.L574= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as COSV53379071; called by muse, mutect2, varscan2
- CFAP46 | c.5619C>T p.L1873= | Silent (SNP) | VAF 92/322 reads (29%) | called by muse, mutect2, varscan2
- CHADL | c.1428C>T p.I476= | Silent (SNP) | VAF 28/131 reads (21%) | called by muse, mutect2, varscan2
- CHRNA9 | c.393G>A p.V131= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as rs1196893614; called by muse, mutect2, varscan2
- CHST5 | c.642G>T p.A214= | Silent (SNP) | VAF 232/562 reads (41%) | catalogued as COSV100292091; called by muse, mutect2, varscan2
- CLCC1 | c.1017G>A p.L339= (on ENST00000356970 / NM_001377464.1; = p.L289= on NM_015127.5) | Silent (SNP) | VAF 20/134 reads (15%) | called by muse, mutect2, varscan2
- CLVS1 | c.285T>C p.A95= | Silent (SNP) | VAF 47/250 reads (19%) | called by muse, mutect2, varscan2
- CNNM2 | c.2121G>A p.A707= | Silent (SNP) | VAF 25/132 reads (19%) | catalogued as rs755761869; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNTNAP5 | c.1941T>A p.P647= | Silent (SNP) | VAF 57/163 reads (35%) | called by muse, mutect2, varscan2
- COPRS | c.471C>G p.P157= | Silent (SNP) | VAF 60/204 reads (29%) | called by muse, mutect2, varscan2
- CPS1 | c.2136C>T p.I712= | Silent (SNP) | VAF 51/185 reads (28%) | called by muse, mutect2, varscan2
- CREBBP | c.4761G>A p.K1587= | Silent (SNP) | VAF 150/599 reads (25%) | called by muse, mutect2, varscan2
- CSMD3 | c.102G>T p.L34= | Silent (SNP) | VAF 43/542 reads (8%) | called by muse, mutect2
- CSNK1A1 | c.1011C>T p.F337= | Silent (SNP) | VAF 18/121 reads (15%) | called by muse, mutect2, varscan2
- CYP3A7 | c.948C>T p.F316= | Silent (SNP) | VAF 104/480 reads (22%) | catalogued as rs781002724; called by muse, mutect2, varscan2
- DDC | c.48C>T p.Y16= | Silent (SNP) | VAF 224/600 reads (37%) | catalogued as rs745576871, COSV63564632; called by muse, mutect2, varscan2
- DDIT4L | c.132C>G p.L44= | Silent (SNP) | VAF 56/203 reads (28%) | called by muse, mutect2, varscan2
- DDX54 | c.2490G>A p.L830= | Silent (SNP) | VAF 42/377 reads (11%) | called by muse, mutect2, varscan2
- DIDO1 | c.5223G>A p.Q1741= | Silent (SNP) | VAF 43/256 reads (17%) | called by muse, mutect2, varscan2
- DLGAP3 | c.711G>A p.R237= | Silent (SNP) | VAF 26/206 reads (13%) | catalogued as rs1179146663; called by muse, mutect2, varscan2
- DNAAF2 | c.1236C>T p.V412= | Silent (SNP) | VAF 75/265 reads (28%) | called by muse, mutect2, varscan2
- DYNC2I2 | c.936C>T p.F312= | Silent (SNP) | VAF 48/176 reads (27%) | catalogued as rs570806137, COSV100823758, COSV63987085; called by muse, mutect2, varscan2
- DYSF | c.4464G>A p.R1488= | Silent (SNP) | VAF 126/548 reads (23%) | catalogued as COSV50498186; called by muse, mutect2, varscan2
- EPN1 | c.1695C>T p.G565= (on ENST00000270460 / NM_001321263.1; = p.G539= on NM_013333.3) | Silent (SNP) | VAF 22/133 reads (17%) | catalogued as rs745478291; called by muse, mutect2, varscan2
- FAM217A | c.99C>A p.G33= | Silent (SNP) | VAF 223/352 reads (63%) | called by muse, mutect2, varscan2
- FAM47C | c.114G>A p.L38= | Silent (SNP) | VAF 49/130 reads (38%) | catalogued as COSV63726479; called by muse, mutect2, varscan2
- FAM71E2 | c.219C>A p.A73= | Silent (SNP) | VAF 17/176 reads (10%) | called by muse, mutect2, varscan2
- FLNC | c.7971C>T p.T2657= | Silent (SNP) | VAF 100/263 reads (38%) | catalogued as rs758833148; ClinVar: likely benign; called by muse, mutect2, varscan2
- FSCN3 | c.1446C>T p.T482= | Silent (SNP) | VAF 46/220 reads (21%) | called by muse, mutect2, varscan2
- FSTL5 | c.2055A>T p.S685= | Silent (SNP) | VAF 41/134 reads (31%) | called by muse, mutect2, varscan2
- GNA14 | c.207G>A p.K69= | Silent (SNP) | VAF 118/304 reads (39%) | catalogued as rs1401641195; called by muse, mutect2, varscan2
- GPAT4 | c.63C>T p.V21= | Silent (SNP) | VAF 37/225 reads (16%) | called by muse, mutect2, varscan2
- GPR101 | c.1281C>T p.V427= | Silent (SNP) | VAF 40/66 reads (61%) | catalogued as COSV53238371; called by muse, mutect2, varscan2
- GPR26 | c.402G>T p.A134= | Silent (SNP) | VAF 158/385 reads (41%) | catalogued as rs1210799362; called by muse, mutect2, varscan2
- GREB1 | c.4272G>A p.L1424= | Silent (SNP) | VAF 24/160 reads (15%) | catalogued as rs772826104, COSV52190854; called by muse, mutect2, varscan2
- GTPBP10 | c.528A>T p.A176= | Silent (SNP) | VAF 53/129 reads (41%) | called by muse, mutect2, varscan2
- H1-7 | c.351C>T p.A117= | Silent (SNP) | VAF 137/362 reads (38%) | catalogued as rs372377328; called by muse, mutect2, varscan2
- H2BC5 | c.198C>T p.F66= | Silent (SNP) | VAF 120/539 reads (22%) | catalogued as rs769305558, COSV56801251; called by muse, mutect2, varscan2
- HECW2 | c.2307G>T p.G769= | Silent (SNP) | VAF 5/11 reads (45%) | called by mutect2, varscan2
- HELZ2 | c.1092G>T p.L364= | Silent (SNP) | VAF 79/338 reads (23%) | catalogued as rs969452966; called by muse, mutect2, varscan2
- HHIP | c.1023C>A p.V341= | Silent (SNP) | VAF 31/200 reads (16%) | called by muse, mutect2, varscan2
- HNRNPH3 | c.801G>A p.L267= | Silent (SNP) | VAF 21/118 reads (18%) | called by muse, mutect2, varscan2
- HRNR | c.8025A>T p.S2675= | Silent (SNP) | VAF 140/1420 reads (10%) | called by muse, varscan2
- HSPA5 | c.450C>G p.L150= | Silent (SNP) | VAF 25/98 reads (26%) | called by muse, mutect2, varscan2
- HTRA4 | c.123C>A p.P41= | Silent (SNP) | VAF 288/758 reads (38%) | called by muse, mutect2, varscan2
- IGFN1 | c.1695G>A p.P565= (on ENST00000295591 / NM_001367841.1; = p.P3022= on NM_001164586.2) | Silent (SNP) | VAF 53/85 reads (62%) | catalogued as rs748911925, COSV55175762; called by muse, mutect2, varscan2
- IGSF23 | c.39T>G p.P13= | Silent (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- ITGA8 | c.1191C>T p.N397= | Silent (SNP) | VAF 28/184 reads (15%) | called by muse, mutect2, varscan2
- KIR3DL1 | c.777G>A p.G259= | Silent (SNP) | VAF 278/578 reads (48%) | catalogued as rs748348047, COSV100428259; called by muse, varscan2
- KRI1 | c.951C>T p.I317= | Silent (SNP) | VAF 54/234 reads (23%) | catalogued as COSV57264811, COSV57266112; called by muse, varscan2
- KRT75 | c.576G>A p.V192= | Silent (SNP) | VAF 55/444 reads (12%) | called by muse, mutect2, varscan2
- LAMA2 | c.1737G>A p.P579= | Silent (SNP) | VAF 16/266 reads (6%) | catalogued as rs149000261; called by muse, mutect2
- LAMA2 | c.5184G>A p.L1728= | Silent (SNP) | VAF 34/215 reads (16%) | called by muse, varscan2
- LCN12 | c.33C>A p.L11= | Silent (SNP) | VAF 160/325 reads (49%) | called by muse, mutect2, varscan2
- LHCGR | c.2034G>A p.L678= | Silent (SNP) | VAF 26/196 reads (13%) | catalogued as COSV99038899; called by muse, mutect2, varscan2
- LIPH | c.883C>T p.L295= | Silent (SNP) | VAF 18/147 reads (12%) | called by muse, mutect2, varscan2
- LOXHD1 | c.5985C>T p.D1995= (on ENST00000642948; = p.D1933= on NM_144612.7) | Silent (SNP) | VAF 26/147 reads (18%) | catalogued as rs559560065; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- LRP12 | c.702C>T p.P234= | Silent (SNP) | VAF 75/205 reads (37%) | catalogued as rs753344591; called by muse, mutect2, varscan2
- LRRC18 | c.705C>A p.T235= | Silent (SNP) | VAF 105/242 reads (43%) | catalogued as COSV53285674; called by muse, mutect2, varscan2
- LRRC7 | c.4170C>A p.G1390= (on ENST00000651989 / NM_001370785.2; = p.G1310= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- LRWD1 | c.411G>A p.L137= | Silent (SNP) | VAF 41/165 reads (25%) | called by muse, mutect2, varscan2
- LYSMD1 | c.279G>C p.L93= | Silent (SNP) | VAF 153/368 reads (42%) | called by muse, mutect2, varscan2
- M1AP | c.927G>A p.V309= | Silent (SNP) | VAF 27/146 reads (18%) | called by muse, mutect2
- MADCAM1 | c.267C>A p.A89= | Silent (SNP) | VAF 92/164 reads (56%) | called by muse, mutect2, varscan2
- MAP2K2 | c.222G>A p.R74= | Silent (SNP) | VAF 120/475 reads (25%) | called by muse, mutect2, varscan2
- MAP4K3 | c.1086A>C p.S362= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV55713623; called by muse, mutect2
- MARCHF11 | c.822G>A p.Q274= | Silent (SNP) | VAF 115/217 reads (53%) | catalogued as rs1456678007; called by muse, mutect2, varscan2
- MCM3AP | c.5028A>T p.P1676= | Silent (SNP) | VAF 34/70 reads (49%) | called by muse, mutect2, varscan2
- MDH2 | c.150G>A p.V50= | Silent (SNP) | VAF 63/301 reads (21%) | catalogued as rs1563546853; called by muse, mutect2, varscan2
- MFGE8 | c.258C>T p.I86= | Silent (SNP) | VAF 46/480 reads (10%) | catalogued as rs770672965; called by muse, mutect2
- MGAM2 | c.3762C>T p.L1254= | Silent (SNP) | VAF 35/190 reads (18%) | called by muse, mutect2, varscan2
- MITF | c.15G>T p.S5= | Silent (SNP) | VAF 82/189 reads (43%) | called by muse, mutect2, varscan2
- MKI67 | c.9552G>A p.Q3184= | Silent (SNP) | VAF 54/340 reads (16%) | called by muse, mutect2, varscan2
- MORC4 | c.2580G>A p.L860= | Silent (SNP) | VAF 48/80 reads (60%) | called by muse, mutect2, varscan2
- MRI1 | c.411C>G p.L137= | Silent (SNP) | VAF 27/82 reads (33%) | called by muse, mutect2, varscan2
- MYEOV | c.651C>T p.L217= | Silent (SNP) | VAF 79/324 reads (24%) | called by muse, mutect2, varscan2
- MYO5C | c.5133C>G p.L1711= | Silent (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- MYRF | c.2367G>A p.L789= (on ENST00000278836 / NM_001127392.3; = p.L780= on NM_013279.4) | Silent (SNP) | VAF 39/165 reads (24%) | called by muse, mutect2, varscan2
- NBEAL2 | c.981C>T p.F327= | Silent (SNP) | VAF 84/197 reads (43%) | called by muse, varscan2
- NCAM1 | c.2205C>A p.L735= (on ENST00000316851 / NM_181351.5; = p.L725= on NM_000615.7) | Silent (SNP) | VAF 197/413 reads (48%) | catalogued as COSV100377243; called by muse, mutect2, varscan2
- NECTIN1 | c.351G>A p.E117= | Silent (SNP) | VAF 116/197 reads (59%) | called by muse, mutect2, varscan2
- NF1 | c.7839G>T p.P2613= (on ENST00000358273 / NM_001042492.3; = p.P2592= on NM_000267.3) | Silent (SNP) | VAF 39/342 reads (11%) | catalogued as COSV62198495; called by muse, mutect2, varscan2
- NLRP2 | c.930G>A p.K310= | Silent (SNP) | VAF 46/202 reads (23%) | called by muse, mutect2, varscan2
- NOA1 | c.633G>T p.R211= | Silent (SNP) | VAF 43/138 reads (31%) | called by muse, mutect2, varscan2
- NPEPPS | c.2217C>T p.L739= | Silent (SNP) | VAF 26/304 reads (9%) | catalogued as rs755555335; called by muse, mutect2
- NPHP4 | c.1035C>T p.L345= | Silent (SNP) | VAF 54/175 reads (31%) | called by muse, mutect2, varscan2
- NRAP | c.4752G>A p.Q1584= (on ENST00000359988 / NM_001322945.2; = p.Q1549= on NM_006175.4) | Silent (SNP) | VAF 130/569 reads (23%) | called by muse, mutect2, varscan2
- NSD2 | c.2628G>A p.K876= | Silent (SNP) | VAF 8/129 reads (6%) | catalogued as COSV56397862; called by muse, mutect2
- NTNG1 | c.1101C>T p.F367= | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as rs753926757; called by muse, mutect2, varscan2
- NTRK1 | c.1824C>A p.A608= | Silent (SNP) | VAF 104/192 reads (54%) | catalogued as COSV62329027; called by muse, mutect2, varscan2
- NUDT17 | c.345G>C p.L115= | Silent (SNP) | VAF 90/222 reads (41%) | called by muse, mutect2, varscan2
- OR10Z1 | c.639C>T p.F213= | Silent (SNP) | VAF 147/388 reads (38%) | called by muse, mutect2, varscan2
- OR2T3 | c.606G>A p.T202= | Silent (SNP) | VAF 24/332 reads (7%) | catalogued as rs1443833489, COSV62082972; called by muse, mutect2
- OR2T3 | c.744C>A p.S248= | Silent (SNP) | VAF 15/275 reads (5%) | catalogued as COSV62082857; called by muse, mutect2
- OR51B6 | c.411C>A p.T137= | Silent (SNP) | VAF 54/107 reads (50%) | catalogued as COSV66513749; called by muse, mutect2, varscan2
- OR5I1 | c.102G>C p.L34= | Silent (SNP) | VAF 41/85 reads (48%) | called by muse, mutect2, varscan2
- ORC4 | c.1275G>C p.V425= | Silent (SNP) | VAF 19/217 reads (9%) | called by muse, mutect2
- ORC4 | c.603C>T p.L201= | Silent (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2, varscan2
- OTX1 | c.57G>T p.G19= | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as COSV56995591; called by muse, mutect2, varscan2
- PAPPA2 | c.4945C>T p.L1649= | Silent (SNP) | VAF 33/255 reads (13%) | catalogued as COSV62793465; called by muse, mutect2, varscan2
- PCARE | c.2235G>A p.R745= | Silent (SNP) | VAF 38/146 reads (26%) | catalogued as rs1558488925, COSV59057138; called by muse, mutect2, varscan2
- PCDHB12 | c.1641G>C p.V547= | Silent (SNP) | VAF 346/764 reads (45%) | catalogued as COSV53396510; called by muse, mutect2, varscan2
- PCDHGA4 | c.2154G>T p.S718= | Silent (SNP) | VAF 76/142 reads (54%) | called by muse, mutect2, varscan2
- PCNT | c.9078G>A p.L3026= | Silent (SNP) | VAF 36/143 reads (25%) | catalogued as rs910156892, CD080882; called by muse, mutect2, varscan2
- PCSK6 | c.2421C>T p.C807= | Silent (SNP) | VAF 37/171 reads (22%) | catalogued as rs558140987, COSV61857469; called by muse, mutect2, varscan2
- PDS5A | c.36C>T p.A12= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs1313199431; called by muse, mutect2
- PELO | c.291G>T p.G97= | Silent (SNP) | VAF 38/200 reads (19%) | called by muse, mutect2, varscan2
- PGBD1 | c.276C>T p.F92= | Silent (SNP) | VAF 42/219 reads (19%) | catalogued as COSV99460702; called by muse, mutect2, varscan2
- PHF10 | c.750C>A p.V250= | Silent (SNP) | VAF 36/158 reads (23%) | catalogued as COSV59323219; called by muse, mutect2, varscan2
- PIEZO1 | c.1374C>T p.S458= | Silent (SNP) | VAF 73/369 reads (20%) | called by muse, mutect2, varscan2
- PIWIL1 | c.39C>A p.A13= | Silent (SNP) | VAF 153/323 reads (47%) | called by muse, mutect2, varscan2
- PKHD1 | c.11739C>T p.R3913= | Silent (SNP) | VAF 236/394 reads (60%) | catalogued as COSV64402284; called by muse, mutect2, varscan2
- PLCH2 | c.3663C>G p.P1221= | Silent (SNP) | VAF 146/336 reads (43%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.1984C>T p.L662= (on ENST00000283426; = p.L1018= on NM_052909.5) | Silent (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
- PLOD3 | c.1434G>A p.Q478= | Silent (SNP) | VAF 104/555 reads (19%) | catalogued as rs780324767; called by muse, mutect2, varscan2
- PLPPR4 | c.1194C>T p.I398= | Silent (SNP) | VAF 103/231 reads (45%) | called by muse, mutect2, varscan2
- PLXNA3 | c.84G>A p.V28= | Silent (SNP) | VAF 82/149 reads (55%) | called by muse, mutect2, varscan2
- PLXNA4 | c.4968G>A p.K1656= | Silent (SNP) | VAF 118/636 reads (19%) | called by muse, mutect2, varscan2
- PNKP | c.897G>T p.P299= | Silent (SNP) | VAF 192/608 reads (32%) | catalogued as COSV55590258; called by mutect2, varscan2
- POSTN | c.366G>A p.L122= | Silent (SNP) | VAF 67/196 reads (34%) | catalogued as COSV101123315; called by muse, mutect2, varscan2
- POTEA | c.237C>T p.P79= | Silent (SNP) | VAF 78/277 reads (28%) | catalogued as rs1335246567; called by muse, mutect2, varscan2
- PPIP5K1 | c.3582C>T p.F1194= (on ENST00000396923; = p.F1169= on NM_014659.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV100288719; called by muse, mutect2, varscan2
- PPP1R32 | c.801C>T p.F267= | Silent (SNP) | VAF 44/227 reads (19%) | catalogued as COSV100087839, COSV58546697; called by muse, mutect2, varscan2
- PPP1R3G | c.18G>A p.A6= | Silent (SNP) | VAF 46/339 reads (14%) | catalogued as rs1442135797; called by muse, mutect2, varscan2
- PRAMEF15 | c.384C>G p.L128= | Silent (SNP) | VAF 46/1022 reads (5%) | called by muse, mutect2
- PRAMEF20 | c.1005C>T p.F335= | Silent (SNP) | VAF 97/647 reads (15%) | catalogued as rs1228418899; called by muse, mutect2, varscan2
- PRAMEF5 | c.378C>G p.L126= | Silent (SNP) | VAF 18/259 reads (7%) | called by muse, mutect2
- PRR14L | c.4812G>C p.L1604= | Silent (SNP) | VAF 27/153 reads (18%) | called by muse, mutect2, varscan2
- PRRT4 | c.1701C>T p.F567= | Silent (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- PTGIR | c.330C>A p.L110= | Silent (SNP) | VAF 84/308 reads (27%) | catalogued as COSV52193503; called by muse, varscan2
- PTPN20 | c.909G>A p.V303= | Silent (SNP) | VAF 26/102 reads (25%) | called by mutect2, varscan2
- RBM11 | c.72G>A p.E24= | Silent (SNP) | VAF 47/281 reads (17%) | called by muse, mutect2, varscan2
- RGS7 | c.138C>G p.V46= | Silent (SNP) | VAF 31/535 reads (6%) | catalogued as rs750723470; called by muse, mutect2
- RIC1 | c.3222G>A p.V1074= | Silent (SNP) | VAF 48/172 reads (28%) | called by muse, mutect2, varscan2
- RPL21 | c.21G>A p.K7= | Silent (SNP) | VAF 92/239 reads (38%) | called by muse, mutect2, varscan2
- RPTN | c.855G>A p.Q285= | Silent (SNP) | VAF 105/769 reads (14%) | catalogued as rs1422499101; called by muse, mutect2, varscan2
- RYR3 | c.11535C>T p.V3845= (on ENST00000389232; = p.V3846= on NM_001036.6) | Silent (SNP) | VAF 18/164 reads (11%) | called by muse, mutect2, varscan2
153 further variants in this file (0 protein-altering or splice-affecting, 43 silent, 110 other) are not listed here.
